Somatic mutation profile of tumor specimen C3N-00825-03 (aliquot CPT0094280010) from CPTAC case C3N-00825, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 53.9 years (19,686 days).
Specimen C3N-00825-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a876808c-2f60-489b-9bec-db77f58a4e40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00825-31 (Blood Derived Normal), aliquot CPT0094340002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/722b2fae-e95f-41ea-bd2c-1b3cdcb47b3e

The open-access MAF lists 59 somatic variants for this specimen: 36 protein-altering or splice-affecting, 13 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 13, Intron 8, Nonsense Mutation 6, Splice Site 3, 5'UTR 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.329G>A p.W110* | Nonsense Mutation (SNP) | VAF 80/452 reads (18%) | hotspot (GDC flag); catalogued as rs1057519852, COSV58682976, COSV58690849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CAPRIN1 | c.1978C>T p.R660W | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767579185, COSV100403908; called by muse, mutect2
- EI24 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as rs1051274719, COSV99629220; called by muse, mutect2
- INMT | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757254092; called by muse, mutect2, varscan2
- ITGA10 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 35/439 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); catalogued as COSV100994615; called by muse, mutect2
- KIAA1328 | c.58+1G>A p.X20_splice | Splice Site (SNP) | VAF 16/145 reads (11%) | catalogued as COSV54468237; called by muse, mutect2, varscan2
- LHX3 | c.554A>C p.H185P (on ENST00000371748 / NM_178138.6; = p.H190P on NM_014564.5) | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs1205070187; called by muse, mutect2, varscan2
- LRP1B | c.3018C>A p.C1006* | Nonsense Mutation (SNP) | VAF 18/158 reads (11%) | catalogued as COSV67260003; called by muse, mutect2, varscan2
- MYH11 | c.3227C>T p.A1076V | Missense Mutation (SNP) | VAF 57/344 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.523); catalogued as rs371205331; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OFD1 | c.1817C>G p.S606* | Nonsense Mutation (SNP) | VAF 22/277 reads (8%) | catalogued as COSV60793888; called by muse, mutect2
- OR51D1 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 38/390 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374266379; called by muse, mutect2
- PASK | c.3668-1G>A p.X1223_splice | Splice Site (SNP) | VAF 32/414 reads (8%) | catalogued as COSV52155079; called by muse, mutect2
- PPFIA3 | c.2306G>A p.R769H | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs566360934, COSV61950895; called by muse, mutect2, varscan2
- SLCO2B1 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 80/293 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs764735701, COSV56934315, COSV56940034; called by muse, mutect2, varscan2
- SURF6 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs782371172, COSV64395311; called by muse, varscan2
- TAF4 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1404427235; called by muse, mutect2, varscan2
- TP53 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 57/313 reads (18%) | catalogued as CM044725, COSV52746809, COSV52814837, COSV53366474; called by muse, mutect2, varscan2
- ZBTB17 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs148471565; called by muse, mutect2
- ARFGAP2 | c.730A>G p.I244V | Missense Mutation (SNP) | VAF 10/304 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2
- C4A | c.3352C>T p.Q1118* | Nonsense Mutation (SNP) | VAF 68/852 reads (8%) | called by muse, mutect2
- DMXL1 | c.8403+1G>C p.X2801_splice | Splice Site (SNP) | VAF 18/118 reads (15%) | called by muse, mutect2, varscan2
- EEF2 | c.263T>C p.F88S | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.697); called by muse, mutect2
- ERCC6 | c.3330G>C p.E1110D | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- FLOT1 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 35/355 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- GMCL2 | c.720G>C p.L240F | Missense Mutation (SNP) | VAF 36/404 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.22); called by muse, mutect2
- HPGD | c.727A>G p.M243V | Missense Mutation (SNP) | VAF 31/338 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.123); called by muse, mutect2
- KLHL1 | c.1658G>A p.G553D | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); called by muse, mutect2
- KLHL4 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 27/196 reads (14%) | called by muse, mutect2, varscan2
- KRT14 | c.731_732dup p.E245Rfs*6 | Frame Shift Ins (INS) | VAF 44/398 reads (11%) | called by mutect2, pindel, varscan2
- LRRN3 | c.840dup p.S281* | Frame Shift Ins (INS) | VAF 12/142 reads (8%) | called by mutect2, pindel
- LTBP2 | c.1901A>G p.D634G | Missense Mutation (SNP) | VAF 100/750 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTX1 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- REST | c.2914C>T p.P972S | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SLC29A4 | c.1537C>A p.H513N | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.055); called by muse, mutect2
- SP6 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2
- TACR3 | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUBN | c.9339C>T p.C3113= | Silent (SNP) | VAF 31/511 reads (6%) | catalogued as rs758802682, COSV64711354; called by muse, mutect2
- DENND5A | c.78G>A p.T26= | Silent (SNP) | VAF 14/338 reads (4%) | called by muse, mutect2
- GPR78 | c.576G>A p.S192= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV66763293; called by muse, mutect2, varscan2
- GRK1 | c.1098C>T p.G366= | Silent (SNP) | VAF 19/168 reads (11%) | catalogued as rs145195020, COSV59553449; called by muse, mutect2, varscan2
- IFNGR1 | c.117C>G p.S39= | Silent (SNP) | VAF 28/355 reads (8%) | catalogued as rs770973014; called by muse, mutect2
- KCNK18 | c.372C>T p.P124= | Silent (SNP) | VAF 48/516 reads (9%) | catalogued as rs763861678; called by muse, mutect2
- PNMA8B | c.1332C>T p.D444= | Silent (SNP) | VAF 21/194 reads (11%) | catalogued as rs370979395; called by muse, mutect2, varscan2
- RNF170 | c.225T>C p.A75= | Silent (SNP) | VAF 30/416 reads (7%) | called by muse, mutect2
- RXFP3 | c.1317G>A p.A439= | Silent (SNP) | VAF 26/229 reads (11%) | catalogued as COSV100347742; called by muse, mutect2, varscan2
- SHANK1 | c.3393G>A p.S1131= | Silent (SNP) | VAF 13/126 reads (10%) | called by muse, mutect2, varscan2
- TMEM130 | c.600C>T p.I200= | Silent (SNP) | VAF 12/268 reads (4%) | called by muse, mutect2
- TMIGD3 | c.615G>A p.K205= (on ENST00000369717 / NM_001081976.2; = p.K286= on NM_020683.7) | Silent (SNP) | VAF 30/318 reads (9%) | called by muse, mutect2
- ZNF215 | c.135G>A p.E45= | Silent (SNP) | VAF 31/369 reads (8%) | called by muse, mutect2
- AC244517.10 | c.36-9073C>T | Intron (SNP) | VAF 74/703 reads (11%) | catalogued as rs1416574600, COSV73145033; called by muse, mutect2, varscan2
- AGXT2 | c.675+42G>A | Intron (SNP) | VAF 18/324 reads (6%) | called by muse, mutect2
- BLOC1S5-TXNDC5 | c.372+39754G>A | Intron (SNP) | VAF 20/248 reads (8%) | catalogued as rs767128341; called by muse, mutect2
- C22orf42 | c.493+16T>A | Intron (SNP) | VAF 34/254 reads (13%) | catalogued as rs562690680, COSV66075696; called by mutect2, varscan2
- CACNA1B | c.530+9496C>T | Intron (SNP) | VAF 7/136 reads (5%) | catalogued as rs866711025; called by muse, mutect2
- DNAH5 | c.799-48G>A | Intron (SNP) | VAF 12/115 reads (10%) | catalogued as rs763157804, COSV54225721; called by muse, mutect2
- PPIP5K2 | c.-359T>G | 5'UTR (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- PRAP1 | c.-39G>A | 5'UTR (SNP) | VAF 11/238 reads (5%) | called by muse, mutect2
- TTN | c.10360+5279A>T | Intron (SNP) | VAF 30/251 reads (12%) | called by muse, mutect2, varscan2
- ZCWPW2 | c.493-456C>T | Intron (SNP) | VAF 5/50 reads (10%) | catalogued as COSV67499238; called by muse, mutect2
